Somatic mutation profile of tumor specimen TCGA-JX-A3Q8-01A (aliquot TCGA-JX-A3Q8-01A-11D-A21Q-09) from TCGA case TCGA-JX-A3Q8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 40.6 years (14,839 days).
Specimen TCGA-JX-A3Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24f1f3eb-03d6-4e38-bb77-a09aed008af7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JX-A3Q8-10A (Blood Derived Normal), aliquot TCGA-JX-A3Q8-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2805a79-bc94-4e0b-8035-372aba76f8a4

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Splice Site 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.4546C>T p.P1516S (on ENST00000614293; = p.P1486S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352121996, COSV55804681; called by muse, mutect2, varscan2
- ABCB4 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as rs758669761, COSV55939617; called by muse, mutect2, varscan2
- ANO7 | c.1688T>A p.I563N (on ENST00000274979; = p.I509N on NM_001370694.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV51476341; called by muse, mutect2, varscan2
- ATP6V0A1 | c.196+1G>C p.X66_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52876615; called by muse, mutect2, varscan2
- B3GNTL1 | c.408+2T>A p.X136_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV57952109; called by muse, mutect2, varscan2
- CDPF1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs763187970, COSV53080557; called by muse, mutect2, varscan2
- CYP2A13 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs267605496, COSV57837112; called by muse, mutect2, varscan2
- DMD | c.4795G>A p.A1599T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV63778612; called by muse, mutect2, varscan2
- FFAR3 | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59909478; called by muse, mutect2, varscan2
- FLNA | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as CD092208, COSV61048621; called by muse, mutect2, varscan2
- GRAMD1B | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs764839388, COSV59208806; called by muse, mutect2, varscan2
- IL26 | c.171+2T>C p.X57_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV57489666; called by muse, mutect2, varscan2
- IQCN | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs1012884589, COSV66576331; called by muse, mutect2, varscan2
- KHK | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53149777, COSV53151311; called by muse, mutect2, varscan2
- KRTAP26-1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62128547, COSV62129172; called by mutect2, varscan2
- LIPE | c.1955G>C p.G652A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54924544; called by muse, mutect2, varscan2
- MAST3 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV53218729; called by muse, mutect2
- MIGA2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.428); catalogued as COSV52978047; called by muse, mutect2, varscan2
- MUC5AC | c.16858C>T p.P5620S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.253); catalogued as rs757532921, COSV64369338; called by muse, mutect2
- NOP14 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV58626863; called by muse, mutect2, varscan2
- NPY5R | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV58453231; called by muse, mutect2, varscan2
- OR51B4 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66517559; called by muse, mutect2, varscan2
- OR5D14 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV59457743; called by muse, mutect2, varscan2
- OR5D16 | c.197A>C p.N66T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101004089, COSV65722584; called by muse, mutect2, varscan2
- OR5D16 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV65722588; called by muse, mutect2, varscan2
- PAPLN | c.1033C>T p.R345C (on ENST00000554301; = p.R318C on NM_173462.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.75); catalogued as rs556246074, COSV53721651; called by muse, mutect2, varscan2
- PCDHA8 | c.1934A>C p.H645P | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV65330716; called by muse, mutect2, varscan2
- PDE1B | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV54494950; called by muse, mutect2, varscan2
- RAD51AP1 | c.407T>C p.M136T (on ENST00000228843 / NM_001130862.2; = p.M119T on NM_006479.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV57411412; called by muse, mutect2, varscan2
- RPS6KA5 | c.470A>C p.Y157S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100002974; called by muse, mutect2, varscan2
- SAA2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as rs766267295, COSV56777339; called by muse, mutect2, varscan2
- SNAPC4 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV53736136; called by muse, mutect2, varscan2
- STAR | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as CM156733, COSV52417364, COSV52418173; called by muse, mutect2, varscan2
- TG | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55088743; called by muse, mutect2, varscan2
- TMEM175 | c.605T>G p.F202C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs771515337, COSV53280382, COSV99298226; called by muse, mutect2, varscan2
- TRPM2 | c.2793G>A p.M931I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs376205676, COSV55974448; called by muse, mutect2, varscan2
- TSHZ2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs766567178, COSV61590431; called by muse, mutect2, varscan2
- TTF2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65633323; called by muse, mutect2
- VCPIP1 | c.2807A>T p.D936V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100125740; called by muse, mutect2
- ZC3H11A | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV59746600; called by muse, mutect2, varscan2
- ANGPT1 | c.1054_1055dup p.G353Pfs*22 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.2076C>G p.D692E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TAF15 | c.962G>T p.R321I (on ENST00000605844 / NM_139215.3; = p.R318I on NM_003487.4) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ABCA10 | c.2358C>T p.I786= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs138668476, COSV99289094; called by muse, mutect2, varscan2
- AK5 | c.616T>C p.L206= (on ENST00000354567 / NM_174858.3; = p.L180= on NM_012093.4) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV58356698; called by muse, mutect2, varscan2
- BACH2 | c.1977G>A p.A659= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs777547219, COSV57602930; called by muse, mutect2, varscan2
- C1QTNF12 | c.852G>A p.G284= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs989963921, COSV57803091; called by muse, mutect2, varscan2
- CHIA | c.291A>G p.G97= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100588773; called by muse, mutect2, varscan2
- CTDSPL2 | c.534A>G p.Q178= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as rs753772537, COSV52947515; called by muse, mutect2, varscan2
- HNRNPM | c.1113G>A p.R371= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs746832500, COSV100335346; called by muse, mutect2, varscan2
- IRAK2 | c.171G>A p.T57= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs572521578, COSV56531405; called by muse, mutect2, varscan2
- MASP2 | c.390C>T p.F130= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1357867222, COSV68897203; called by muse, mutect2, varscan2
- MFSD4A | c.714G>T p.L238= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100901662; called by mutect2, varscan2
- STAT1 | c.1959C>T p.V653= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV63117117; called by muse, mutect2, varscan2
- XKR4 | c.1233C>A p.I411= | Silent (SNP) | VAF 72/171 reads (42%) | catalogued as COSV59332240; called by muse, mutect2, varscan2
- ZNF767P | n.310G>A | RNA (SNP) | VAF 17/42 reads (40%) | catalogued as rs773454525; called by muse, mutect2, varscan2
